Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAH8, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAH8-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 9,0 cm; no angio-invasion; no invasion in rete-testis;
no invasion of tunica albuginea.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD-O-3
Seminoma NOS 9061/3
Site (R) Testis NOS 8629
JW 3/7/14

Source: NCI Genomic Data Commons file 608db87c-043d-4e18-accd-8648f1624f43 (TCGA-2G-AAH8.C9D6E7C5-4860-4E7A-8FAC-018E500CC0DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).